Somatic mutation profile of tumor specimen 0DR20E from CCDI case PBCDWD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain stem; Age at diagnosis: 3.9 years (1,436 days).
Specimen 0DR20E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae5bcfc5-91fd-42d9-bd00-536aa87b3be3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR1YL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00df2d32-c58b-4bca-8f91-074e78bb3a2d

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 618/1353 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FTMT | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 16/448 reads (4%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs1452340515, COSV58420210; called by muse, mutect2
- PLXNB3 | c.5129C>A p.T1710N | Missense Mutation (SNP) | VAF 65/537 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs144227320; called by muse, mutect2, varscan2
- RAI1 | c.5600T>C p.I1867T | Missense Mutation (SNP) | VAF 78/366 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as rs1387867262; called by muse, mutect2, varscan2
- ZBED4 | c.3347C>T p.A1116V | Missense Mutation (SNP) | VAF 174/925 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.207); catalogued as rs376380218; called by muse, mutect2, varscan2
- PLXND1 | c.3051C>T p.N1017= | Silent (SNP) | VAF 119/524 reads (23%) | catalogued as rs368770401; called by muse, mutect2, varscan2
- RSBN1L | c.*82C>T | 3'UTR (SNP) | VAF 38/182 reads (21%) | catalogued as rs1312645808; called by muse, mutect2, varscan2
